Gene-level copy-number profile of tumor specimen TCGA-YL-A8S8-01A from TCGA case TCGA-YL-A8S8, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.8 years (25,119 days).
Specimen TCGA-YL-A8S8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a4741b59-022f-464f-b233-2ed1f736ba01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A8S8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc3c2436-a0d3-4ce3-99e3-2d2dfaf8006d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 5,663; copy number 2: 38,929; copy number 3: 11,411; copy number 4: 3,729; copy number 5: 7; copy number 6: 6; copy number 7: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A8S8-01A-11D-A376-01): tumor purity 0.61, ploidy 2.3, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:143,601,517–143,964,156, 7 genes (within-gene range 0–2): AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1, Y_RNA, AC016910.1.
- chr2:155,263,458–155,330,527, 8 genes: MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P.
- chr2:183,897,950–184,939,492, 9 genes: AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33.
- chr2:186,694,060–187,003,377, 3 genes (within-gene range 0–2): FAM171B, ZSWIM2, IMPDH1P7.
- chr2:187,122,562–187,122,861, 1 gene: RN7SKP42.
- chr11:37,702,125–38,686,323, 8 genes: AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493.
- chr13:59,010,332–59,263,391, 4 genes: HMGN2P39, POLR3KP1, AL159156.1, RPP40P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,377,244–174,378,005, 1 gene, copy number 5: AC069218.1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 5: RN7SKP40.
- chr4:76,435,229–76,783,253, 5 genes, copy number 5 (within-gene range 3–5): SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH.
- chr7:98,211,439–98,401,090, 6 genes, copy number 6: BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26.
- chr7:147,080,934–147,167,572, 3 genes, copy number 7: CNTNAP2-AS1, DUTP3, RANP2.

Autosomal genes at a single copy (total copy number 1): 3,270. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
